Somatic mutation profile of tumor specimen TCGA-YB-A89D-01A (aliquot TCGA-YB-A89D-01A-12D-A36O-08) from TCGA case TCGA-YB-A89D, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Body of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 59.7 years (21,792 days).
Specimen TCGA-YB-A89D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9eb6876e-7e93-4cdb-a903-363d44c5e72b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YB-A89D-10A (Blood Derived Normal), aliquot TCGA-YB-A89D-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38d1b32d-026a-420b-bafb-566e61df2c5f

The open-access MAF lists 28 somatic variants for this specimen: 20 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 6, Nonsense Mutation 1, Frame Shift Del 1, Splice Region 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 82/472 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 87/390 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80338963, CD147870, CM040450, CM041789, CM981228, COSV61683972, COSV61685418, COSV61686083; ClinVar: likely pathogenic / not provided / pathogenic; called by muse, mutect2, varscan2
- CDKN2A | c.262del p.E88Rfs*58 | Frame Shift Del (DEL) | VAF 26/121 reads (21%) | catalogued as rs1329443726, CM034218, CM095540, COSV58683071, COSV58683670; called by mutect2, pindel, varscan2
- CSMD3 | c.10334C>T p.A3445V (on ENST00000297405 / NM_001363185.1; = p.A3276V on NM_052900.3) | Missense Mutation (SNP) | VAF 55/550 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.428); catalogued as COSV52248662, COSV99850884; called by muse, mutect2, varscan2
- DNAI4 | c.850G>T p.D284Y | Missense Mutation (SNP) | VAF 89/1024 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100925249; called by muse, mutect2
- ECT2 | c.208A>C p.K70Q | Missense Mutation (SNP) | VAF 31/288 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99222040; called by muse, mutect2, varscan2
- FOLH1 | c.1308G>A p.E436= | Splice Region (SNP) | VAF 34/606 reads (6%) | catalogued as COSV57046790, COSV99924075; called by muse, mutect2
- MGAT3 | c.1552C>T p.P518S | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as COSV100362105; called by muse, mutect2
- MTERF3 | c.676A>T p.R226W | Missense Mutation (SNP) | VAF 100/540 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1228456163, COSV99750201; called by muse, mutect2, varscan2
- MYO18B | c.2609C>T p.T870I | Missense Mutation (SNP) | VAF 214/802 reads (27%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.567); catalogued as rs1482373201, COSV59149371; called by muse, mutect2, varscan2
- NUGGC | c.198G>C p.Q66H | Missense Mutation (SNP) | VAF 97/546 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1373334913, COSV100429880; called by muse, mutect2, varscan2
- PCDHA9 | c.16C>T p.R6* | Nonsense Mutation (SNP) | VAF 90/810 reads (11%) | catalogued as COSV100970195; called by muse, varscan2
- PTPRG | c.4003G>A p.V1335I | Missense Mutation (SNP) | VAF 113/1066 reads (11%) | SIFT tolerated (0.73); PolyPhen benign (0.036); catalogued as rs1174651225, COSV55638927; called by muse, mutect2
- RP1 | c.3095A>G p.N1032S | Missense Mutation (SNP) | VAF 227/1079 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.014); catalogued as rs1310943793, COSV99609123; called by muse, mutect2, varscan2
- SLC25A13 | c.1064G>A p.R355Q | Missense Mutation (SNP) | VAF 70/359 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs398122839, CM141650, COSV99674389; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- SLIT2 | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 117/527 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs192894188, COSV56562325; called by muse, mutect2, varscan2
- SPATA18 | c.1577G>A p.R526Q | Missense Mutation (SNP) | VAF 129/666 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs562919654, COSV54644150; called by muse, mutect2, varscan2
- TCP1 | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 72/645 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as rs1304892322, COSV100365109; called by muse, mutect2, varscan2
- TNRC6B | c.1768C>T p.R590C | Missense Mutation (SNP) | VAF 82/751 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57294478; called by muse, mutect2, varscan2
- ZNF497 | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.629); catalogued as rs781189020, COSV54050595; called by muse, mutect2, varscan2
- ADAMTS2 | c.2883C>T p.D961= | Silent (SNP) | VAF 72/790 reads (9%) | catalogued as rs370397254; ClinVar: likely benign; called by muse, mutect2
- CDH4 | c.2721G>A p.A907= | Silent (SNP) | VAF 10/298 reads (3%) | catalogued as rs374087046; called by muse, mutect2
- CTSC | c.822A>G p.L274= | Silent (SNP) | VAF 50/502 reads (10%) | catalogued as COSV99911030; called by muse, mutect2, varscan2
- MGAT3 | c.903C>A p.V301= | Silent (SNP) | VAF 81/639 reads (13%) | catalogued as COSV100362099; called by muse, mutect2, varscan2
- MGAT3 | c.1137C>T p.I379= | Silent (SNP) | VAF 48/420 reads (11%) | catalogued as COSV100362101; called by muse, mutect2, varscan2
- MGAT3 | c.1284C>T p.I428= | Silent (SNP) | VAF 19/175 reads (11%) | catalogued as COSV100362103; called by muse, mutect2, varscan2
- DDHD1 | c.1846+2552C>A | Intron (SNP) | VAF 19/87 reads (22%) | catalogued as rs772528960, COSV60358625; called by muse, mutect2, varscan2
- TAOK2 | chr16:29989670 A>G | 3'Flank (SNP) | VAF 40/245 reads (16%) | catalogued as rs1442278141, COSV99663399; called by muse, mutect2, varscan2
